Gene-level copy-number profile of tumor specimen TCGA-CF-A5UA-01A from TCGA case TCGA-CF-A5UA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 67.4 years (24,625 days).
Specimen TCGA-CF-A5UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a81cc240-b5cf-43a9-999d-b306f56af276.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A5UA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8dde9c06-06b3-46bb-b7fd-713cebd4e57e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 5,917; copy number 2: 42,150; copy number 3: 6,190; copy number 4: 1,310; copy number 5: 3,633; copy number 6: 196; copy number 9: 47; copy number 10: 131; copy number 12: 71; copy number 17: 8; copy number 22: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A5UA-01A-11D-A288-01): tumor purity 0.92, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–24,905,735, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,168 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,062,081, 728 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–97,149,654, 769 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:31,505,280–36,487,548, 196 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr12:66,767–32,993,754, 832 genes, copy number 5 (broad region; genes not listed).
- chr12:49,323,236–56,414,045, 373 genes, copy number 5–10 (broad region; genes not listed).
- chr12:64,507,001–70,637,440, 138 genes, copy number 9–22 (within-gene range 1–22) (broad region; genes not listed).
- chr12:92,421,531–94,009,047, 35 genes, copy number 10 (within-gene range 1–10): AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA, MRPL42, RN7SL737P, AC025260.1, SOCS2-AS1, SOCS2, AC012085.1, CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1, AC012464.3, RN7SKP263.
- chr12:107,809,483–107,912,620, 6 genes, copy number 9: AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1.
- chr12:109,347,903–117,190,471, 188 genes, copy number 5–17 (broad region; genes not listed).
- chr17:3,276,942–7,329,393, 193 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
